Somatic mutation profile of tumor specimen TCGA-P5-A5EW-01A (aliquot TCGA-P5-A5EW-01A-11D-A27K-08) from TCGA case TCGA-P5-A5EW, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 20.8 years (7,612 days).
Specimen TCGA-P5-A5EW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e67997b6-7a6a-4889-b71d-0305570fe12f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P5-A5EW-10A (Blood Derived Normal), aliquot TCGA-P5-A5EW-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56ec4e4a-6248-4aae-89cc-53826b4703ae

The open-access MAF lists 15 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 8, Silent 4, Frame Shift Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 25/56 reads (45%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 42/45 reads (93%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CCDC105 | c.1271G>T p.C424F | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV52963543; called by muse, mutect2, varscan2
- CDCP1 | c.2429A>G p.H810R | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as COSV56104436; called by muse, mutect2
- CYP39A1 | c.1370C>T p.P457L | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1164249719, COSV51494384, COSV51500209; called by muse, mutect2, varscan2
- GABRP | c.844G>A p.V282M | Missense Mutation (SNP) | VAF 87/174 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760731394, COSV54662009; called by muse, mutect2, varscan2
- MAGEA6 | c.703del p.E235Kfs*50 | Frame Shift Del (DEL) | VAF 134/334 reads (40%) | catalogued as COSV61449432; called by mutect2, varscan2
- NOTCH2 | c.5519G>A p.G1840D | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99867816; called by muse, mutect2
- OPHN1 | c.1139-2A>G p.X380_splice | Splice Site (SNP) | VAF 15/48 reads (31%) | catalogued as COSV62781227; called by muse, mutect2, varscan2
- TMCC2 | c.208A>G p.K70E | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV63663134; called by muse, mutect2, varscan2
- ATRX | c.986_990del p.K329Ifs*3 | Frame Shift Del (DEL) | VAF 20/56 reads (36%) | called by pindel, varscan2
- FBXL6 | c.1053C>T p.P351= | Silent (SNP) | VAF 64/124 reads (52%) | catalogued as rs781893569, COSV57351337; called by muse, mutect2, varscan2
- KRI1 | c.1209C>T p.D403= | Silent (SNP) | VAF 22/99 reads (22%) | catalogued as rs766794774, COSV57264096; called by muse, mutect2, varscan2
- LRRC32 | c.1627C>T p.L543= | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as COSV52632200; called by muse, mutect2, varscan2
- PCDHGA1 | c.1005C>A p.I335= | Silent (SNP) | VAF 36/97 reads (37%) | catalogued as COSV65295645, COSV65296315; called by muse, mutect2, varscan2
